Somatic mutation profile of tumor specimen TCGA-2H-A9GO-01A (aliquot TCGA-2H-A9GO-01A-11D-A37C-09) from TCGA case TCGA-2H-A9GO, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 58.8 years (21,486 days).
Specimen TCGA-2H-A9GO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 34166364-5e97-4466-8553-cb25c06fd957.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-2H-A9GO-11A (Solid Tissue Normal), aliquot TCGA-2H-A9GO-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b2f8736d-6dc5-46bf-bdee-67ce8f85fb79

The open-access MAF lists 150 somatic variants for this specimen: 106 protein-altering or splice-affecting, 40 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 40, Nonsense Mutation 6, Frame Shift Ins 2, Splice Site 2, RNA 2, 3'UTR 1, Frame Shift Del 1, Splice Region 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ING1 | c.1015C>T p.R339* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | hotspot (GDC flag); catalogued as COSV58167363; called by mutect2, varscan2
- TP53 | c.337T>G p.F113V | Missense Mutation (SNP) | VAF 56/97 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781642, COSV52677695, COSV53351693; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3472C>T p.R1158* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as COSV65894008; called by muse, mutect2, varscan2
- ADGRD1 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.71); PolyPhen benign (0.006); catalogued as COSV55442179; called by muse, mutect2, varscan2
- APBB1IP | c.909C>A p.F303L | Missense Mutation (SNP) | VAF 15/43 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV66131809; called by muse, mutect2, varscan2
- BTN3A1 | c.1319A>C p.K440T | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.348); catalogued as rs753391625, COSV50024451; called by muse, mutect2, varscan2
- CNTN5 | c.492A>C p.E164D | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as COSV54307950; called by muse, mutect2, varscan2
- COL7A1 | c.3584C>T p.A1195V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs552219889; called by mutect2, varscan2
- DAAM2 | c.1445C>T p.T482M | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.683); catalogued as rs192352327; called by muse, mutect2, varscan2
- DENND4B | c.232G>A p.E78K | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.506); catalogued as COSV57840787; called by muse, mutect2, varscan2
- DNAH5 | c.9302A>G p.K3101R | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.67); catalogued as COSV54231490; called by muse, mutect2, varscan2
- EPHA5 | c.394T>G p.F132V | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56674693, COSV99897673; called by muse, mutect2, varscan2
- EZHIP | c.169G>A p.G57S | Missense Mutation (SNP) | VAF 35/44 reads (80%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as COSV100539677; called by muse, mutect2, varscan2
- FAM107B | c.94G>A p.D32N (on ENST00000378458 / NM_001320737.1; = p.D207N on NM_031453.3) | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as rs748855567; called by muse, mutect2, varscan2
- FBN2 | c.7282C>T p.P2428S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.692); catalogued as COSV52490989; called by muse, mutect2, varscan2
- GDA | c.838G>A p.G280S | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.938); catalogued as rs551530651, COSV52991447; called by muse, mutect2, varscan2
- H1-3 | c.401G>C p.G134A | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs148166404; called by mutect2, varscan2
- IGHM | c.1030C>T p.R344W | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs782579930; called by muse, mutect2, varscan2
- KCNF1 | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.105); catalogued as COSV54462381, COSV54463231; called by muse, mutect2, varscan2
- KCNT2 | c.2897T>G p.L966R | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.418); catalogued as COSV54069295, COSV54070653, COSV54077408; called by muse, mutect2, varscan2
- KIF9 | c.1685C>T p.P562L | Missense Mutation (SNP) | VAF 21/53 reads (40%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.608); catalogued as rs201012739, COSV99646993; called by muse, mutect2, varscan2
- KRT6B | c.203A>G p.K68R | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV52886001; called by muse, varscan2
- LRP1B | c.4820A>T p.D1607V | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV67265809; called by muse, mutect2, varscan2
- MCPH1 | c.2185G>A p.E729K | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs575824036; called by muse, mutect2, varscan2
- NCOR1 | c.6728C>A p.T2243K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.025); catalogued as COSV51991485; called by muse, mutect2, varscan2
- NLRP13 | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs79874516, COSV61622099; called by muse, mutect2, varscan2
- OLFM1 | c.1399G>A p.G467S (on ENST00000371793 / NM_001282611.2; = p.G449S on NM_014279.5) | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs774962345, COSV53278064; called by muse, mutect2, varscan2
- OR14K1 | c.494A>C p.N165T | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV51722034, COSV51722298; called by muse, mutect2, varscan2
- OR4F15 | c.861C>G p.Y287* | Nonsense Mutation (SNP) | VAF 12/64 reads (19%) | catalogued as COSV59969050; called by muse, mutect2, varscan2
- OR5H15 | c.439T>G p.L147V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.79); PolyPhen possibly damaging (0.595); catalogued as rs745398251; called by muse, mutect2, varscan2
- OTOGL | c.4582C>T p.P1528S (on ENST00000547103; = p.P1519S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs774362283; called by muse, mutect2, varscan2
- PCDHA8 | c.265C>T p.R89W | Missense Mutation (SNP) | VAF 19/120 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.499); catalogued as rs1327577851; called by muse, mutect2, varscan2
- PHKA1 | c.8G>A p.S3N | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.754); catalogued as rs782367579; called by muse, mutect2
- PLSCR5 | c.503A>C p.K168T | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.088); catalogued as COSV101494484; called by muse, mutect2, varscan2
- PRDM14 | c.710C>A p.S237Y | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.325); catalogued as COSV52573853, COSV99399983; called by muse, mutect2, varscan2
- PXDN | c.1865C>T p.P622L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0.279); catalogued as rs368643195; called by muse, mutect2, varscan2
- PXDNL | c.3450C>G p.I1150M | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.491); catalogued as COSV62479427, COSV62488429; called by muse, mutect2, varscan2
- RPS6KA6 | c.1060C>T p.P354S | Missense Mutation (SNP) | VAF 67/108 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.038); catalogued as COSV99424668; called by muse, mutect2, varscan2
- SPTA1 | c.2465G>C p.G822A | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV63757476, COSV63760331; called by muse, mutect2, varscan2
- SYT1 | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.343); catalogued as COSV54042380, COSV99695097; called by muse, mutect2, varscan2
- TG | c.4504G>A p.A1502T | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0.012); catalogued as COSV99600684; called by muse, mutect2, varscan2
- TG | c.6712del p.L2238Wfs*12 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | catalogued as COSV55087538; called by mutect2, pindel, varscan2
- TGFBR1 | c.1240C>G p.R414G | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM112281; called by muse, mutect2, varscan2
- TSC22D1 | c.559G>A p.G187R | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs1436445368, COSV101488187; called by muse, mutect2, varscan2
- TTN | c.49286G>A p.R16429K (on ENST00000591111; = p.R9005K on NM_003319.4) | Missense Mutation (SNP) | VAF 24/77 reads (31%) | PolyPhen probably damaging (0.987); catalogued as COSV100617685, COSV60138642; called by muse, mutect2, varscan2
- UMOD | c.207C>A p.C69* | Nonsense Mutation (SNP) | VAF 12/59 reads (20%) | catalogued as rs1218858441; called by muse, mutect2, varscan2
- VCAN | c.979C>T p.R327C | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54101721; called by muse, mutect2, varscan2
- ZNF425 | c.1271G>A p.R424H | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.215); catalogued as rs1165656351, COSV65201205; called by muse, mutect2, varscan2
- ZNF804B | c.791A>T p.K264M | Missense Mutation (SNP) | VAF 39/52 reads (75%) | SIFT tolerated (0.32); PolyPhen benign (0.035); catalogued as COSV60853182; called by muse, mutect2, varscan2
- ABCA12 | c.4349G>A p.W1450* (on ENST00000272895 / NM_173076.3; = p.W1132* on NM_015657.3) | Nonsense Mutation (SNP) | VAF 32/57 reads (56%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AMIGO2 | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ARHGAP32 | c.2919A>C p.E973D (on ENST00000310343 / NM_001378025.1; = p.E624D on NM_014715.4) | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BAZ2B | c.1363A>C p.I455L | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- C1QB | c.639G>T p.K213N | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- CDK19 | c.813A>C p.R271S | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.217); called by muse, mutect2
- COL4A6 | c.3524G>T p.G1175V | Missense Mutation (SNP) | VAF 41/63 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSAD | c.31G>T p.A11S (on ENST00000444623 / NM_001244705.2; = p.A38S on NM_015989.5) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.68); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CUBN | c.5700A>C p.E1900D | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- DNAH7 | c.8045C>T p.A2682V | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.1265A>C p.E422A | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FANCD2 | c.2483A>C p.K828T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- FGF1 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- GLP2R | c.412T>G p.L138V | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- GOLGA2 | c.277-1G>C p.X93_splice | Splice Site (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- HTATSF1 | c.915_917del p.L306del | In Frame Del (DEL) | VAF 18/43 reads (42%) | called by mutect2, pindel, varscan2
- HTR1E | c.720G>T p.Q240H | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2
- ITCH | c.261G>C p.Q87H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (1); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ITSN2 | c.3681C>A p.D1227E | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KLHL15 | c.1743G>C p.K581N | Missense Mutation (SNP) | VAF 21/36 reads (58%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- LCOR | c.1077C>G p.N359K | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- MBNL1 | c.277A>C p.M93L | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- MROH2B | c.1864A>C p.T622P | Missense Mutation (SNP) | VAF 71/120 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NPFFR2 | c.559T>G p.L187V | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- NSD3 | c.3808A>T p.R1270* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | called by muse, mutect2, varscan2
- OR10G8 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1L3 | c.253T>G p.F85V | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- PCDH18 | c.1761A>C p.E587D | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PCDH9 | c.108A>C p.E36D | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PHC2 | c.2150C>T p.T717I (on ENST00000257118 / NM_198040.2; = p.T182I on NM_004427.4) | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.006); called by muse, mutect2
- PLEKHG5 | c.3064C>G p.L1022V (on ENST00000400915 / NM_001042663.3; = p.L985V on NM_020631.6) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PPFIA2 | c.3308A>G p.K1103R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PPP1R17 | c.56A>T p.K19M | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PRKDC | c.7529dup p.L2510Ffs*4 | Frame Shift Ins (INS) | VAF 16/69 reads (23%) | called by mutect2, pindel, varscan2
- RBAK | c.652G>A p.A218T | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (0.57); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- RFX6 | c.1816C>A p.Q606K | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.033); called by muse, mutect2
- RIMS1 | c.4772A>G p.K1591R | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RYR3 | c.3265T>C p.F1089L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SH3RF3 | c.2111A>C p.N704T | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.2); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SI | c.2025dup p.G676Wfs*8 | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- SLIT2 | c.2276+1G>T p.X759_splice | Splice Site (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- SMC5 | c.2889G>A p.E963= | Splice Region (SNP) | VAF 14/51 reads (27%) | called by muse, mutect2, varscan2
- SPTA1 | c.1058A>G p.E353G | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SULF1 | c.1309A>G p.K437E | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.324); called by muse, mutect2, varscan2
- SYNE1 | c.8693G>A p.S2898N (on ENST00000367255 / NM_182961.4; = p.S2905N on NM_033071.3) | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.56); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TET2 | c.2081T>G p.L694R | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- TICRR | c.655T>G p.L219V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- TLR4 | c.2264A>C p.Q755P (on ENST00000355622 / NM_138554.5; = p.Q715P on NM_003266.4) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TMPRSS6 | c.1120T>G p.F374V | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- TRBV27 | c.175G>A p.G59R | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRHDE | c.2246A>C p.K749T | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.92); PolyPhen benign (0.006); called by muse, mutect2
- ZFAND4 | c.1982A>C p.K661T | Missense Mutation (SNP) | VAF 78/114 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZNF212 | c.840C>A p.S280R | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF493 | c.535A>C p.T179P | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- ZNF583 | c.1088A>G p.H363R | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.46); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- ZNF598 | c.620G>A p.R207H | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTS16 | c.2539A>C p.R847= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- AP3D1 | c.2682G>A p.Q894= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- ASAH2 | c.852G>A p.L284= | Silent (SNP) | VAF 200/440 reads (45%) | called by muse, mutect2, varscan2
- BAIAP2 | c.735G>A p.Q245= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs767161879; called by muse, varscan2
- BRAT1 | c.1506C>T p.F502= | Silent (SNP) | VAF 9/134 reads (7%) | called by muse, mutect2
- CFAP61 | c.816C>T p.D272= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs181125825, COSV55633098; called by muse, mutect2, varscan2
- COX7C | c.42C>T p.V14= | Silent (SNP) | VAF 7/58 reads (12%) | catalogued as rs1014515359; called by muse, mutect2, varscan2
- CTNND2 | c.102C>T p.G34= | Silent (SNP) | VAF 8/94 reads (9%) | called by muse, mutect2
- DCLRE1C | c.735C>G p.L245= (on ENST00000378278 / NM_001350965.2; = p.L130= on NM_022487.4) | Silent (SNP) | VAF 19/64 reads (30%) | catalogued as COSV100739793; called by muse, mutect2
- DNAH2 | c.10326C>T p.N3442= | Silent (SNP) | VAF 16/75 reads (21%) | catalogued as rs758800240, COSV66716203; called by muse, mutect2, varscan2
- DOCK1 | c.4215C>T p.F1405= | Silent (SNP) | VAF 5/64 reads (8%) | catalogued as rs1432709594; called by muse, mutect2
- ELMO1 | c.141A>G p.E47= | Silent (SNP) | VAF 5/57 reads (9%) | called by muse, mutect2
- FLT4 | c.108G>A p.E36= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as rs1477174819; called by muse, mutect2, varscan2
- FSIP2 | c.19359A>G p.K6453= | Silent (SNP) | VAF 11/53 reads (21%) | catalogued as COSV58083976; called by muse, mutect2, varscan2
- GRIK3 | c.183A>C p.R61= | Silent (SNP) | VAF 26/71 reads (37%) | called by muse, mutect2, varscan2
- GYS1 | c.426G>A p.P142= | Silent (SNP) | VAF 25/57 reads (44%) | catalogued as rs767467759; called by muse, mutect2, varscan2
- KLHL26 | c.1749G>A p.T583= | Silent (SNP) | VAF 24/96 reads (25%) | catalogued as rs368665940; called by muse, mutect2, varscan2
- KRTAP26-1 | c.159A>G p.T53= | Silent (SNP) | VAF 20/57 reads (35%) | called by muse, mutect2, varscan2
- LDLR | c.1992G>A p.V664= | Silent (SNP) | VAF 11/51 reads (22%) | called by muse, mutect2, varscan2
- MAGEB3 | c.327C>T p.D109= | Silent (SNP) | VAF 20/30 reads (67%) | called by muse, mutect2, varscan2
- MEA1 | c.339G>A p.E113= | Silent (SNP) | VAF 7/48 reads (15%) | called by muse, mutect2, varscan2
- MRGPRX3 | c.210G>A p.A70= | Silent (SNP) | VAF 26/40 reads (65%) | catalogued as rs749919475, COSV66934205; called by muse, mutect2, varscan2
- NCEH1 | c.18G>T p.G6= | Silent (SNP) | VAF 23/79 reads (29%) | catalogued as COSV56439231; called by muse, mutect2, varscan2
- NKRF | c.942A>G p.P314= | Silent (SNP) | VAF 7/46 reads (15%) | catalogued as rs1384627442; called by muse, mutect2, varscan2
- PCDHA12 | c.288C>T p.C96= | Silent (SNP) | VAF 25/129 reads (19%) | catalogued as rs781811926, COSV56501287; called by muse, mutect2, varscan2
- PCDHB16 | c.435C>T p.N145= | Silent (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- PCNX2 | c.3609C>T p.A1203= | Silent (SNP) | VAF 34/60 reads (57%) | catalogued as COSV50864291; called by muse, mutect2, varscan2
- PLBD2 | c.354C>T p.A118= | Silent (SNP) | VAF 26/45 reads (58%) | catalogued as rs761709953, COSV99785304; called by muse, mutect2, varscan2
- PRDM14 | c.300G>A p.P100= | Silent (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- RASGRP4 | c.1806C>T p.P602= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- SFRP4 | c.108C>A p.P36= | Silent (SNP) | VAF 5/53 reads (9%) | called by muse, mutect2, varscan2
- SLC25A6 | c.576C>T p.F192= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as rs191387595, COSV67317521; called by muse, mutect2, varscan2
- SORL1 | c.4935G>A p.R1645= | Silent (SNP) | VAF 24/46 reads (52%) | catalogued as rs1265935844; called by muse, mutect2, varscan2
- SOX3 | c.225A>T p.A75= | Silent (SNP) | VAF 20/28 reads (71%) | called by muse, mutect2, varscan2
- SYT9 | c.963A>G p.Q321= | Silent (SNP) | VAF 48/80 reads (60%) | catalogued as rs925984946; called by muse, mutect2, varscan2
- TAS2R10 | c.835C>T p.L279= | Silent (SNP) | VAF 22/52 reads (42%) | catalogued as COSV53700768; called by muse, mutect2, varscan2
- TMEM132B | c.2637G>A p.P879= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as rs191297957; called by muse, mutect2, varscan2
- ZBBX | c.1425T>C p.T475= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as COSV56785528; called by muse, mutect2, varscan2
- ZFP28 | c.2268T>G p.P756= | Silent (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- ZNF345 | c.1326T>G p.T442= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as COSV100080322; called by muse, mutect2, varscan2
- MIR622 | n.6A>C | RNA (SNP) | VAF 8/29 reads (28%) | called by muse, mutect2, varscan2
- NPR3 | c.*3114T>C | 3'UTR (SNP) | VAF 11/45 reads (24%) | catalogued as COSV54089417, COSV54089868; called by muse, mutect2, varscan2
- SNORD116-8 | n.42G>A | RNA (SNP) | VAF 16/94 reads (17%) | catalogued as rs776123863; called by muse, mutect2, varscan2
- ZNF99 | c.4-653T>C | Intron (SNP) | VAF 10/54 reads (19%) | called by muse, mutect2, varscan2
